TCGA case TCGA-EE-A3AD — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: University of Sydney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0f1fb775-c4a2-4a1e-8b09-f935233cdaee

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 50 years; Vital status: Dead; Days to death: 875 days (2.4 years).

Diagnoses (7)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.0; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: Progression; Age at diagnosis: 50.6 years (18,491 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T0; AJCC pathologic N: N1b; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 875 days (2.4 years); Melanoma known primary: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: BRAF Inhibitor; Days to treatment start: 632 days (1.7 years); Treatment outcome: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Spinal cord. Age at diagnosis: 52.1 years (19,045 days); Days to diagnosis: 554 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 554 days (1.5 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Connective, subcutaneous and other soft tissues of abdomen. Age at diagnosis: 52.2 years (19,058 days); Days to diagnosis: 567 days (1.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
4. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Lung, NOS. Age at diagnosis: 52.2 years (19,058 days); Days to diagnosis: 567 days (1.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
5. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Connective, subcutaneous and other soft tissues of thorax. Age at diagnosis: 52.2 years (19,058 days); Days to diagnosis: 567 days (1.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
6. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Brain, NOS. Age at diagnosis: 52.4 years (19,139 days); Days to diagnosis: 648 days (1.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 771 days (2.1 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.
7. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Liver. Age at diagnosis: 52.4 years (19,139 days); Days to diagnosis: 648 days (1.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (8 entries)
- Days to follow up: 112 days; Disease response: Tumor Free.
- Day 554 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Spinal cord; Days to progression: 554 days (1.5 years).
- Day 567 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues of thorax; Days to progression: 567 days (1.6 years).
- Day 567 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues of abdomen; Days to progression: 567 days (1.6 years).
- Day 567 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 567 days (1.6 years).
- Day 648 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 648 days (1.8 years).
- Day 648 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 648 days (1.8 years).
- Days to follow up: 875 days (2.4 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EE-A3AD-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EE-A3AD-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 90 mg.
  Slide TCGA-EE-A3AD-06A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 97; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EE-A3AD-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Primary location: Regional Lymph Node; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Subsequent known primaries: No.
- Drug treatment: Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 875 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 875 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 554 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EE-A3AD-06A-11D-A194-01): tumor purity 1, ploidy 3.89, whole-genome doublings 1.
